Gene-level copy-number profile of tumor specimen TCGA-CR-6484-01A from TCGA case TCGA-CR-6484, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.3 years (24,569 days).
Specimen TCGA-CR-6484-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.04d81c5e-988c-42ba-9313-40a4d94f7283.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6484-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2792e909-c6c7-40b2-b6df-078edde7922f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,014; copy number 2: 22,882; copy number 3: 21,636; copy number 4: 7,134; copy number 5: 5,907; copy number 6: 53; copy number 7: 83; copy number 8: 12; copy number 9: 12; copy number 15: 13; copy number 20: 18; copy number 32: 28; copy number 42: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6484-01A-11D-1869-01): tumor purity 0.3, ploidy 2.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 185 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:33,039,417–36,697,867, 78 genes, copy number 15–42 (broad region; genes not listed).
- chr11:40,114,203–41,459,773, 1 gene, copy number 9 (within-gene range 6–9): LRRC4C.
- chr11:41,122,907–46,274,547, 94 genes, copy number 7–9 (broad region; genes not listed).
- chr15:26,008,940–26,970,385, 12 genes, copy number 8: AC044913.1, AC100836.1, LINC00929, AC012060.1, LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1.

Autosomal genes at a single copy (total copy number 1): 1,946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
